Somatic mutation profile of tumor specimen 0DNGGQ from CCDI case PBCBPM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.5 years (6,012 days).
Specimen 0DNGGQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d12e8390-4926-411b-8ffc-cffa7aed0bbc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNGG6 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/54981322-7c9d-47ca-99a0-94ef45620b69

The open-access MAF lists 22 somatic variants for this specimen: 13 protein-altering or splice-affecting, 3 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Intron 4, Silent 3, 3'UTR 2, Splice Region 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 272/712 reads (38%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACSBG1 | c.1423G>A p.G475S | Missense Mutation (SNP) | VAF 122/311 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1255578373, COSV51906787; called by muse, mutect2, varscan2
- ADCY4 | c.1081G>A p.V361M | Missense Mutation (SNP) | VAF 137/308 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1566439435, COSV60255749; called by muse, mutect2, varscan2
- ATRX | c.4795G>T p.G1599C | Missense Mutation (SNP) | VAF 405/452 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64881575; called by muse, mutect2, varscan2
- CD163L1 | c.2804G>A p.R935H | Missense Mutation (SNP) | VAF 170/407 reads (42%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs369458125; called by muse, mutect2, varscan2
- ELL | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 153/369 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as rs746959534; called by muse, mutect2, varscan2
- FGFR1 | c.1638C>G p.N546K (on ENST00000447712 / NM_023110.3; = p.N544K on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 310/365 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58329537, COSV58330551; called by muse, mutect2, varscan2
- GCKR | c.1090C>A p.L364I | Missense Mutation (SNP) | VAF 421/994 reads (42%) | SIFT tolerated (0.48); PolyPhen benign (0.247); catalogued as COSV53110321; called by muse, mutect2, varscan2
- ARHGAP36 | c.1632C>A p.Y544* | Nonsense Mutation (SNP) | VAF 29/230 reads (13%) | called by muse, mutect2, varscan2
- KIF18B | c.1645G>C p.E549Q (on ENST00000593135 / NM_001265577.2; = p.E561Q on NM_001264573.2) | Missense Mutation (SNP) | VAF 290/598 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- KIF2A | c.1280C>G p.S427C | Missense Mutation (SNP) | VAF 22/630 reads (3%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); called by muse, mutect2
- MRC2 | c.2438-6C>T | Splice Region (SNP) | VAF 594/1053 reads (56%) | called by muse, varscan2
- TBX4 | c.702+7C>A | Splice Region (SNP) | VAF 90/702 reads (13%) | called by muse, mutect2, varscan2
- CCER1 | c.111C>T p.S37= | Silent (SNP) | VAF 436/692 reads (63%) | called by muse, mutect2, varscan2
- DHX58 | c.1137C>T p.S379= | Silent (SNP) | VAF 155/628 reads (25%) | catalogued as rs148306396; called by muse, mutect2, varscan2
- LAMA2 | c.5775C>T p.F1925= | Silent (SNP) | VAF 172/1287 reads (13%) | called by muse, mutect2, varscan2
- ARL17A | c.*3874G>A | 3'UTR (SNP) | VAF 13/146 reads (9%) | catalogued as rs200195412, COSV60235811; called by muse, mutect2, varscan2
- DDHD1 | c.1846+80A>C | Intron (SNP) | VAF 22/196 reads (11%) | called by muse, mutect2
- DMC1 | c.494+35T>C | Intron (SNP) | VAF 180/425 reads (42%) | called by muse, mutect2, varscan2
- MRC2 | c.2474-83C>T | Intron (SNP) | VAF 50/174 reads (29%) | called by muse, mutect2, varscan2
- TGFBI | c.*99C>G | 3'UTR (SNP) | VAF 45/128 reads (35%) | called by muse, mutect2, varscan2
- USE1 | c.395-37A>C | Intron (SNP) | VAF 59/127 reads (46%) | called by muse, mutect2, varscan2
